Somatic mutation profile of cancer-model specimen HCM-CSHL-0878-C18-85A (3D Organoid, passage 2; aliquot HCM-CSHL-0878-C18-85A-01D-A882-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0878-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 53.1 years (19,396 days).
Specimen HCM-CSHL-0878-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 2.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83fc030c-176e-4544-8b23-63f4c555481a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0878-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0878-C18-10A-01D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35d9fedb-5827-4305-97a7-3d1a6724d54f

The open-access MAF lists 68 somatic variants for this specimen: 49 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 18, Frame Shift Del 5, Nonsense Mutation 3, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALX4 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 412/810 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777700, CM147007, COSV61324811; called by muse, mutect2, varscan2
- AMER1 | c.1230G>A p.W410* | Nonsense Mutation (SNP) | VAF 733/734 reads (100%) | catalogued as COSV57654654; called by muse, mutect2, varscan2
- APC | c.2744del p.V915Gfs*40 | Frame Shift Del (DEL) | VAF 274/733 reads (37%) | catalogued as COSV57395481; called by mutect2, pindel, varscan2
- CPED1 | c.2216C>T p.T739M | Missense Mutation (SNP) | VAF 282/630 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs145897714; called by muse, mutect2, varscan2
- CROCC | c.3982C>T p.R1328W | Missense Mutation (SNP) | VAF 534/535 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs768033612; called by muse, mutect2, varscan2
- CYSRT1 | c.521G>A p.R174H (on ENST00000409414; = p.R134H on NM_199001.5) | Missense Mutation (SNP) | VAF 555/1128 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1001645598; called by muse, mutect2, varscan2
- DEFB126 | c.109_111del p.K37del | In Frame Del (DEL) | VAF 490/498 reads (98%) | catalogued as rs749729924; called by pindel, varscan2
- FASN | c.6487C>T p.R2163C | Missense Mutation (SNP) | VAF 552/1124 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1031448244; called by muse, mutect2, varscan2
- FREM3 | c.2392C>T p.R798W | Missense Mutation (SNP) | VAF 422/422 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as rs776491489; called by muse, mutect2, varscan2
- FYN | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 324/648 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs1465963577, COSV57609576; called by muse, mutect2, varscan2
- KCNB2 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 515/1024 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867030236, COSV73049898; called by muse, mutect2, varscan2
- MITF | c.770C>T p.S257L (on ENST00000448226 / NM_006722.3; = p.S151L on NM_000248.4) | Missense Mutation (SNP) | VAF 136/315 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs142900294; called by muse, mutect2, varscan2
- PLVAP | c.682C>A p.L228M | Missense Mutation (SNP) | VAF 373/708 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV53085429; called by muse, mutect2, varscan2
- PRRT2 | c.288G>C p.K96N | Missense Mutation (SNP) | VAF 413/878 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs746270404; called by muse, mutect2, varscan2
- RGMA | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 461/463 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs759625610, COSV61236492; called by muse, mutect2, varscan2
- SEMA4F | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 243/505 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764330446, COSV100335919; called by muse, mutect2, varscan2
- STARD8 | c.2074C>T p.R692* | Nonsense Mutation (SNP) | VAF 824/824 reads (100%) | catalogued as COSV52931065; called by muse, mutect2, varscan2
- TARM1 | c.167G>A p.R56Q (on ENST00000616041 / NM_001330650.1; = p.R48Q on NM_001135686.3) | Missense Mutation (SNP) | VAF 472/874 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as rs369139973; called by muse, mutect2, varscan2
- TAS1R3 | c.2537G>T p.G846V | Missense Mutation (SNP) | VAF 310/311 reads (100%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); catalogued as rs749470074; called by muse, mutect2, varscan2
- TDRD15 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 243/509 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1230881059; called by muse, mutect2, varscan2
- TP53 | c.912del p.K305Sfs*40 | Frame Shift Del (DEL) | VAF 310/432 reads (72%) | catalogued as COSV52701088; called by mutect2, pindel, varscan2
- TRIM42 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 429/917 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV53880850, COSV99648250; called by muse, mutect2, varscan2
- TRIM66 | c.2651C>T p.P884L | Missense Mutation (SNP) | VAF 432/851 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1457217588; called by muse, mutect2, varscan2
- UNC93B1 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 200/200 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs769871051, COSV57099262; called by muse, mutect2, varscan2
- ZFHX4 | c.7298C>T p.S2433L | Missense Mutation (SNP) | VAF 544/1087 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1290135493, COSV99257705; called by muse, mutect2, varscan2
- ZNF148 | c.1617G>T p.E539D | Missense Mutation (SNP) | VAF 26/634 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100641903; called by muse, mutect2
- ABCA8 | c.4242G>T p.Q1414H | Missense Mutation (SNP) | VAF 242/487 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ATP13A4 | c.2510A>C p.Q837P | Missense Mutation (SNP) | VAF 201/437 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C2orf16 | c.4831C>T p.Q1611* | Nonsense Mutation (SNP) | VAF 25/945 reads (3%) | called by muse, mutect2
- CCDC194 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 408/834 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- E2F8 | c.1439A>G p.N480S | Missense Mutation (SNP) | VAF 354/788 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ERBB4 | c.327del p.K109Nfs*13 | Frame Shift Del (DEL) | VAF 279/687 reads (41%) | called by mutect2, pindel, varscan2
- IQGAP3 | c.4810G>A p.V1604M | Missense Mutation (SNP) | VAF 221/635 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- LAX1 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 389/958 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LRP10 | c.1031G>C p.C344S | Missense Mutation (SNP) | VAF 442/917 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC73 | c.649_652del p.S217Lfs*8 | Frame Shift Del (DEL) | VAF 198/407 reads (49%) | called by mutect2, pindel, varscan2
- LRRC9 | c.1973A>G p.K658R | Missense Mutation (SNP) | VAF 316/623 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MAP2 | c.4942C>T p.R1648C | Missense Mutation (SNP) | VAF 350/700 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO15B | c.7929G>T p.Q2643H | Missense Mutation (SNP) | VAF 182/452 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ODC1 | c.329A>C p.Y110S | Missense Mutation (SNP) | VAF 241/509 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PCDH11X | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 322/322 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PLXNA1 | c.1885A>G p.T629A | Missense Mutation (SNP) | VAF 296/616 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- PMS1 | c.1628A>T p.E543V | Missense Mutation (SNP) | VAF 168/349 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RSL1D1 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 156/321 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SRCAP | c.2081A>C p.K694T | Missense Mutation (SNP) | VAF 290/617 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STRN3 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 158/381 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- STXBP1 | c.1544T>A p.V515D | Missense Mutation (SNP) | VAF 308/674 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- TET1 | c.3171del p.K1057Nfs*25 | Frame Shift Del (DEL) | VAF 348/805 reads (43%) | called by mutect2, pindel, varscan2
- TFG | c.997A>G p.T333A | Missense Mutation (SNP) | VAF 411/887 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS16 | c.3078C>T p.P1026= | Silent (SNP) | VAF 381/782 reads (49%) | catalogued as rs751814492, COSV56986526; called by muse, mutect2, varscan2
- AHNAK2 | c.8160C>T p.H2720= | Silent (SNP) | VAF 462/905 reads (51%) | catalogued as rs373499038; called by muse, mutect2, varscan2
- C2orf16 | c.3285A>T p.A1095= | Silent (SNP) | VAF 26/951 reads (3%) | called by muse, mutect2
- CHI3L2 | c.858C>A p.A286= | Silent (SNP) | VAF 519/519 reads (100%) | called by muse, mutect2, varscan2
- ERFE | c.351C>T p.P117= | Silent (SNP) | VAF 358/683 reads (52%) | catalogued as rs1271386322; called by muse, mutect2, varscan2
- GMCL1 | c.1062A>G p.V354= | Silent (SNP) | VAF 115/269 reads (43%) | called by muse, varscan2
- IRGC | c.747C>T p.P249= | Silent (SNP) | VAF 456/898 reads (51%) | catalogued as rs1305694225; called by muse, mutect2, varscan2
- ITGB4 | c.615C>T p.N205= | Silent (SNP) | VAF 382/779 reads (49%) | catalogued as rs371826076; called by muse, mutect2, varscan2
- PAPPA2 | c.1290G>A p.S430= | Silent (SNP) | VAF 324/763 reads (42%) | catalogued as rs746898916; called by muse, mutect2, varscan2
- PDE1C | c.1908T>G p.S636= | Silent (SNP) | VAF 310/603 reads (51%) | called by muse, mutect2, varscan2
- POLR3E | c.1356C>T p.A452= | Silent (SNP) | VAF 211/422 reads (50%) | catalogued as rs777492146, COSV55398910; called by muse, mutect2, varscan2
- PTPRG | c.735C>A p.S245= | Silent (SNP) | VAF 274/593 reads (46%) | called by muse, mutect2, varscan2
- RBM38 | c.594G>A p.T198= | Silent (SNP) | VAF 1708/1709 reads (100%) | catalogued as rs751373448, COSV100654857; called by muse, mutect2, varscan2
- RYR2 | c.10047G>A p.S3349= | Silent (SNP) | VAF 369/676 reads (55%) | catalogued as rs144428932, COSV63692145; ClinVar: likely benign; called by muse, mutect2, varscan2
- TENM2 | c.357C>T p.T119= | Silent (SNP) | VAF 322/613 reads (53%) | catalogued as rs1418780607; called by muse, mutect2, varscan2
- TNC | c.4941C>T p.F1647= | Silent (SNP) | VAF 345/752 reads (46%) | catalogued as rs201689087, COSV60788203; called by muse, mutect2, varscan2
- TNN | c.600G>A p.P200= | Silent (SNP) | VAF 630/1149 reads (55%) | catalogued as rs763252970; called by muse, varscan2
- TRAPPC5 | c.354C>T p.I118= | Silent (SNP) | VAF 329/824 reads (40%) | catalogued as rs1467984756; called by muse, mutect2, varscan2
- ETNK1 | c.-200G>T | 5'UTR (SNP) | VAF 448/927 reads (48%) | catalogued as COSV56885133; called by muse, mutect2, varscan2
